Gene-level copy-number profile of tumor specimen TCGA-N8-A4PP-01A from TCGA case TCGA-N8-A4PP, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-N8-A4PP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.89d0e483-19d9-4ffe-807c-0684baa7bf8e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N8-A4PP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/164a4678-1fb6-4235-874f-f9b75eef139c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 4,835; copy number 2: 20,066; copy number 3: 22,449; copy number 4: 6,466; copy number 5: 4,607; copy number 6: 944; copy number 7: 199; copy number 8: 13; copy number 9: 17; copy number 10: 16; copy number 11: 132; copy number 12: 2; copy number 13: 59.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N8-A4PP-01A-11D-A28Q-01): tumor purity 0.53, ploidy 2.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:133,913,677–133,917,269, 1 gene (within-gene range 0–3): WSPAR.
- chr10:75,552,458–75,552,553, 1 gene: MIR606.
- chr21:22,882,582–23,131,206, 5 genes (within-gene range 0–2): AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 438 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,399,560–153,693,992, 132 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr7:88,219,359–89,754,726, 15 genes, copy number 7–9 (within-gene range 4–9): AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P.
- chr8:55,696,424–61,714,640, 93 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr9:4,386,410–4,386,556, 1 gene, copy number 12: RNU6-694P.
- chr10:62,183,035–62,480,288, 5 genes, copy number 9 (within-gene range 3–9): RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365.
- chr11:12,848,795–15,758,898, 49 genes, copy number 7–10 (within-gene range 3–10): AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1.
- chr18:30,290,161–31,963,618, 34 genes, copy number 7–12 (within-gene range 5–12): AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1.
- chr18:43,499,173–47,931,146, 72 genes, copy number 8–13 (broad region; genes not listed).
- chr21:24,840,550–26,573,286, 37 genes, copy number 7 (within-gene range 2–7): LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1.

Autosomal genes at a single copy (total copy number 1): 2,626. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
